Somatic mutation profile of tumor specimen TCGA-RC-A6M4-01A (aliquot TCGA-RC-A6M4-01A-11D-A32G-10) from TCGA case TCGA-RC-A6M4, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 74.8 years (27,327 days).
Specimen TCGA-RC-A6M4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e94909a5-de7a-46eb-8a05-50ce29501893.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RC-A6M4-10A (Blood Derived Normal), aliquot TCGA-RC-A6M4-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/889416b1-1c52-4e48-8442-b26012c99684

The open-access MAF lists 204 somatic variants for this specimen: 146 protein-altering or splice-affecting, 55 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 127, Silent 55, Nonsense Mutation 8, Splice Site 7, Intron 2, Splice Region 1, Frame Shift Ins 1, 3'Flank 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>T p.D32V | Missense Mutation (SNP) | VAF 68/141 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.3050+2T>G p.X1017_splice | Splice Site (SNP) | VAF 29/80 reads (36%) | catalogued as COSV100933033; called by muse, mutect2, varscan2
- ABCC10 | c.1451G>T p.R484L (on ENST00000372530 / NM_001198934.2; = p.R441L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.592); catalogued as COSV55086785, COSV99766761; called by muse, mutect2, varscan2
- ADAMTS12 | c.1294T>C p.W432R | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710339; called by muse, mutect2, varscan2
- AFAP1L1 | c.686G>C p.R229P | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV99695645; called by muse, mutect2, varscan2
- AHNAK2 | c.7345G>T p.V2449L | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.993); catalogued as COSV100315835, COSV60921105; called by muse, mutect2, varscan2
- AHR | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54121404, COSV54127162; called by muse, mutect2, varscan2
- ANXA6 | c.383A>G p.H128R | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1242797859, COSV100636799; called by muse, mutect2, varscan2
- APOB | c.3995C>G p.S1332C | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99263828; called by muse, mutect2, varscan2
- APOB | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99263829; called by muse, mutect2, varscan2
- APOOL | c.86A>G p.E29G | Missense Mutation (SNP) | VAF 235/476 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as COSV100920798; called by muse, mutect2, varscan2
- BCL11B | c.1462T>A p.S488T (on ENST00000357195 / NM_001282237.2; = p.S417T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as COSV100595177; called by muse, mutect2, varscan2
- BIRC6 | c.7450G>C p.D2484H | Missense Mutation (SNP) | VAF 106/207 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV101427870; called by muse, mutect2, varscan2
- BOD1L1 | c.7105A>T p.S2369C | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99238491; called by muse, mutect2, varscan2
- BRINP1 | c.1541C>A p.T514N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV99774519; called by muse, mutect2, varscan2
- BTLA | c.460C>A p.L154I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV100569614; called by muse, mutect2
- CARD11 | c.188C>T p.A63V | Missense Mutation (SNP) | VAF 57/114 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV100712210; called by muse, mutect2, varscan2
- CARD8 | c.664C>G p.L222V (on ENST00000651546 / NM_001184900.3; = p.L172V on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); catalogued as COSV100751005; called by muse, mutect2, varscan2
- CES1 | c.913T>C p.S305P | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.119); catalogued as COSV100828563; called by muse, mutect2, varscan2
- CFAP54 | c.4918T>A p.C1640S | Missense Mutation (SNP) | VAF 135/217 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100732979; called by muse, mutect2, varscan2
- CIZ1 | c.2315C>A p.S772Y | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99476677; called by muse, mutect2, varscan2
- CLDN18 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99480633; called by muse, mutect2, varscan2
- CLIP2 | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs782207729, COSV99791033; called by muse, mutect2, varscan2
- COL18A1 | c.3313-2A>T p.X1105_splice (on ENST00000359759 / NM_130444.3; = p.X870_splice on NM_030582.4) | Splice Site (SNP) | VAF 63/152 reads (41%) | catalogued as COSV100645006; called by muse, mutect2, varscan2
- COL2A1 | c.3350A>T p.D1117V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100475630; called by muse, mutect2, varscan2
- COL4A6 | c.2129T>A p.L710* | Nonsense Mutation (SNP) | VAF 51/116 reads (44%) | catalogued as COSV100563438; called by muse, mutect2, varscan2
- CPA5 | c.607C>A p.H203N | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV100812245; called by muse, mutect2, varscan2
- CRLF1 | c.355C>A p.R119S | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101134936; called by muse, mutect2, varscan2
- CROCC | c.3302G>T p.S1101I | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100978068; called by muse, mutect2, varscan2
- CSAD | c.1082A>C p.D361A (on ENST00000444623 / NM_001244705.2; = p.D388A on NM_015989.5) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99914522; called by muse, varscan2
- CWC22 | c.185A>G p.Y62C | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.527); catalogued as COSV99844013; called by muse, mutect2, varscan2
- DCHS2 | n.1215+1G>C | Splice Site (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100250975; called by muse, mutect2, varscan2
- DENND3 | c.2678C>T p.A893V | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.657); catalogued as rs201075864, COSV99370390; called by muse, mutect2, varscan2
- DENND5B | c.2429A>T p.Q810L | Missense Mutation (SNP) | VAF 79/125 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV100170957; called by muse, mutect2, varscan2
- DNAH8 | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767504389, COSV100543459; called by muse, mutect2, varscan2
- DOCK10 | c.5522A>T p.E1841V | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99287809; called by muse, mutect2, varscan2
- DST | c.10405A>T p.R3469* | Nonsense Mutation (SNP) | VAF 37/129 reads (29%) | catalogued as COSV99751601; called by muse, mutect2, varscan2
- DZIP3 | c.3149+2T>A p.X1050_splice | Splice Site (SNP) | VAF 38/143 reads (27%) | catalogued as COSV100847655; called by muse, mutect2, varscan2
- ENPP6 | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 52/108 reads (48%) | catalogued as COSV99698529; called by muse, mutect2, varscan2
- ERP44 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.224); catalogued as rs1248924033, COSV52430431; called by muse, mutect2, varscan2
- FBLN2 | c.595T>G p.Y199D | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99851464; called by muse, mutect2, varscan2
- FBXO44 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs1381865573, COSV99278751; called by muse, mutect2, varscan2
- FCMR | c.287A>G p.E96G | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); catalogued as COSV100892823; called by muse, mutect2, varscan2
- FLAD1 | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99422122; called by muse, mutect2, varscan2
- FSIP2 | c.16069G>T p.E5357* | Nonsense Mutation (SNP) | VAF 78/159 reads (49%) | catalogued as COSV100554137; called by muse, mutect2, varscan2
- GLB1 | c.317A>T p.Y106F | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.305); catalogued as COSV100256972; called by muse, mutect2, varscan2
- GLB1L3 | c.1844C>A p.P615H | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101345120; called by muse, mutect2, varscan2
- GPR45 | c.388G>A p.V130M | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99306705; called by muse, mutect2, varscan2
- GRIN2D | c.2178T>A p.Y726* | Nonsense Mutation (SNP) | VAF 26/84 reads (31%) | catalogued as COSV99615941; called by muse, mutect2, varscan2
- GSAP | c.1483T>G p.W495G | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99989996; called by muse, mutect2, varscan2
- HMCN1 | c.9223A>T p.T3075S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.422); catalogued as COSV99624577; called by muse, mutect2, varscan2
- HMGN5 | c.334G>T p.G112* | Nonsense Mutation (SNP) | VAF 244/506 reads (48%) | catalogued as COSV100814790; called by muse, mutect2, varscan2
- HNRNPH1 | c.696G>T p.R232S | Missense Mutation (SNP) | VAF 48/77 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.222); catalogued as COSV100270383; called by muse, varscan2
- HTR3D | c.1302C>A p.F434L (on ENST00000382489 / NM_001163646.2; = p.F259L on NM_182537.3) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100487922; called by muse, mutect2
- IDI1 | c.140+1G>A p.X47_splice | Splice Site (SNP) | VAF 20/46 reads (43%) | catalogued as rs1331317313, COSV100830149; called by muse, varscan2
- IFNA6 | c.58T>A p.C20S | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.127); catalogued as COSV101207013; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1441A>T p.R481* | Nonsense Mutation (SNP) | VAF 106/221 reads (48%) | catalogued as COSV100780756; called by muse, mutect2, varscan2
- IL31RA | c.506A>T p.K169I | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51683510, COSV99762850; called by muse, mutect2, varscan2
- ILDR1 | c.873A>T p.K291N (on ENST00000344209 / NM_001199799.2; = p.K247N on NM_175924.4) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99877985; called by muse, mutect2, varscan2
- ITGA10 | c.759-2A>T p.X253_splice | Splice Site (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100994736; called by muse, varscan2
- ITGA9 | c.1380G>T p.R460S | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99291743; called by muse, mutect2, varscan2
- KATNIP | c.2350T>A p.W784R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.4); PolyPhen benign (0.162); catalogued as COSV99849981; called by muse, mutect2, varscan2
- KCNH1 | c.1195A>T p.S399C (on ENST00000271751 / NM_172362.3; = p.S372C on NM_002238.4) | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99657522; called by muse, mutect2, varscan2
- KCNK10 | c.1495T>A p.S499T | Missense Mutation (SNP) | VAF 115/241 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100067648; called by muse, mutect2, varscan2
- KCNQ3 | c.712C>A p.L238M | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101195728; called by muse, mutect2, varscan2
- KIAA1522 | c.689A>T p.E230V (on ENST00000373480 / NM_001198972.2; = p.E289V on NM_020888.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV99614168; called by muse, mutect2, varscan2
- KIAA1614 | c.1424T>A p.V475E | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.715); catalogued as COSV100851157; called by muse, mutect2, varscan2
- KMT2D | c.7717G>A p.G2573S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV99977977; called by muse, mutect2, varscan2
- KRT25 | c.785T>A p.L262H | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100379822; called by muse, mutect2, varscan2
- KRT31 | c.1105A>T p.S369C | Missense Mutation (SNP) | VAF 27/51 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99289422; called by muse, mutect2, varscan2
- LATS1 | c.754A>T p.R252* | Nonsense Mutation (SNP) | VAF 41/47 reads (87%) | catalogued as COSV99485364; called by muse, mutect2, varscan2
- MDM2 | c.948A>C p.E316D | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as rs778582378, COSV99254356; called by muse, mutect2, varscan2
- MPHOSPH9 | c.968A>T p.E323V | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV100186495, COSV56619363; called by muse, mutect2, varscan2
- MTERF1 | c.311A>T p.E104V | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.32); PolyPhen probably damaging (1); catalogued as COSV100699544; called by muse, mutect2, varscan2
- MTSS2 | c.1696C>T p.R566C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55382290; called by muse, mutect2, varscan2
- MXD1 | c.650C>T p.A217V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs765516764, COSV100037426; called by muse, mutect2, varscan2
- MYD88 | c.482T>A p.F161Y | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.602); catalogued as COSV100085852; called by muse, mutect2, varscan2
- MYT1L | c.2930C>G p.P977R | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101216841; called by muse, mutect2, varscan2
- NCOA1 | c.16G>T p.D6Y | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56039037, COSV99945290; called by muse, mutect2, varscan2
- NETO1 | c.1355C>A p.A452D | Missense Mutation (SNP) | VAF 107/187 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV55001305; called by muse, mutect2, varscan2
- NOTCH4 | c.3523G>T p.A1175S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.469); catalogued as COSV100900388, COSV66683292; called by muse, mutect2, varscan2
- NOX1 | c.1225C>G p.P409A | Missense Mutation (SNP) | VAF 152/272 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99471436; called by muse, mutect2, varscan2
- NR0B2 | c.292C>A p.L98I | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV54260157, COSV99574894; called by muse, mutect2, varscan2
- NR4A2 | c.461A>T p.Q154L | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV100276946; called by muse, mutect2, varscan2
- ODR4 | c.53T>A p.I18K | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV99834175; called by muse, mutect2, varscan2
- OPN4 | c.184A>G p.T62A | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99618058; called by muse, mutect2, varscan2
- OR52R1 | c.758C>A p.A253D | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100617614; called by muse, mutect2
- OR6C2 | c.725A>T p.H242L | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100498657; called by muse, mutect2, varscan2
- OR9A4 | c.53G>T p.G18V | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.119); catalogued as rs1391934725, COSV71886297; called by muse, mutect2, varscan2
- PATJ | c.4049A>T p.E1350V | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.15); catalogued as COSV100219442; called by muse, mutect2, varscan2
- PCDHA6 | c.1681A>T p.N561Y | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100971262; called by muse, mutect2, varscan2
- PCDHB6 | c.1507T>A p.S503T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV99169931; called by muse, mutect2, varscan2
- PDE6A | c.491A>G p.D164G | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as rs750240631, COSV99677856; called by muse, mutect2, varscan2
- PHF20 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100179899; called by muse, mutect2, varscan2
- PIP4K2A | c.1037-2A>T p.X346_splice | Splice Site (SNP) | VAF 20/43 reads (47%) | catalogued as COSV100114377, COSV60540802; called by muse, mutect2, varscan2
- PLB1 | c.2545G>A p.D849N | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100577712; called by muse, mutect2, varscan2
- PLCB1 | c.283A>T p.I95F | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV100569492; called by muse, mutect2, varscan2
- PMP22 | c.133T>C p.S45P | Missense Mutation (SNP) | VAF 43/48 reads (90%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100396854; called by muse, mutect2, varscan2
- POLQ | c.26A>T p.K9I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV99951684; called by muse, mutect2, varscan2
- PTK2B | c.2909A>T p.E970V | Missense Mutation (SNP) | VAF 16/17 reads (94%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.911); catalogued as COSV99531915; called by muse, mutect2, varscan2
- RAB18 | c.68G>C p.S23T | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100803777; called by muse, mutect2, varscan2
- RAPGEF5 | c.962A>T p.Q321L | Missense Mutation (SNP) | VAF 72/142 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV100686540; called by muse, mutect2, varscan2
- RHBDL3 | c.536A>G p.Y179C | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99283548; called by muse, mutect2, varscan2
- RNF40 | c.1508G>A p.R503Q | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770007658, COSV100221910; called by muse, mutect2, varscan2
- ROBO1 | c.1100C>A p.T367N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV71394619; called by muse, mutect2, varscan2
- RRAGA | c.455C>T p.S152F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.289); catalogued as COSV100998085; called by muse, mutect2, varscan2
- RTL9 | c.17A>G p.H6R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.011); catalogued as COSV101511629; called by muse, mutect2, varscan2
- RUNX2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 85/145 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.577); catalogued as COSV100176248; called by muse, mutect2, varscan2
- SALL1 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99171582; called by muse, mutect2, varscan2
- SEC31B | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100944800; called by muse, mutect2
- SIRPB1 | c.787A>G p.R263G | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.035); catalogued as COSV99498173; called by muse, mutect2, varscan2
- SLAMF7 | c.694C>A p.L232M | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as COSV100833207, COSV63562779; called by muse, mutect2, varscan2
- SLC10A4 | c.1217A>T p.Y406F | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV56718944; called by muse, mutect2, varscan2
- SLC12A8 | c.1072A>G p.K358E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100101872; called by muse, mutect2, varscan2
- SLC36A2 | c.1057A>T p.T353S | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.186); catalogued as COSV100078941; called by muse, mutect2, varscan2
- SLC41A3 | c.343A>T p.N115Y | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100259380; called by muse, mutect2, varscan2
- SMAD3 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100528741; called by muse, mutect2, varscan2
- SPTA1 | c.6529A>C p.R2177= | Splice Region (SNP) | VAF 37/102 reads (36%) | catalogued as COSV100934368; called by muse, mutect2, varscan2
- STAC | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99829543; called by muse, mutect2, varscan2
- SULF1 | c.2120A>T p.Q707L | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99482226; called by muse, mutect2, varscan2
- TBX18 | c.1282A>T p.N428Y | Missense Mutation (SNP) | VAF 62/68 reads (91%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.56); catalogued as COSV100858437; called by muse, mutect2, varscan2
- TERF1 | c.835A>T p.S279C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV99400963; called by muse, mutect2, varscan2
- THAP4 | c.1424C>T p.T475M | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1301665750, COSV100398198; called by muse, mutect2, varscan2
- THEMIS | c.1628T>C p.M543T | Missense Mutation (SNP) | VAF 28/32 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs768563536, COSV100965262; called by muse, mutect2, varscan2
- TMEM163 | c.545T>C p.L182P | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.041); catalogued as COSV99925733; called by muse, mutect2, varscan2
- TMEM63B | c.1102A>G p.N368D | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV52481255; called by muse, mutect2, varscan2
- TNN | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as rs1023226246, COSV99511186, COSV99513446; called by muse, mutect2, varscan2
- TOP1MT | c.443A>G p.K148R | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.072); catalogued as rs1191548433, COSV100239227; called by muse, mutect2
- TRIM31 | c.262T>C p.S88P | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100946748; called by muse, mutect2, varscan2
- TRIM49 | c.980G>A p.S327N | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV100315901; called by muse, mutect2, varscan2
- TSPYL6 | c.801A>T p.R267S | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.86); PolyPhen benign (0.316); catalogued as COSV100336315; called by muse, mutect2, varscan2
- TUBB8 | c.680A>T p.H227L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.774); catalogued as COSV100225932; called by muse, mutect2
- UGGT1 | c.670A>T p.N224Y | Missense Mutation (SNP) | VAF 89/237 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99390277; called by muse, mutect2, varscan2
- ULK2 | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 102/108 reads (94%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100860672; called by muse, mutect2, varscan2
- UNC13A | c.5042C>A p.A1681D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99406710, COSV99407246; called by muse, mutect2, varscan2
- UNC45B | c.2237T>A p.L746Q | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99268256; called by muse, mutect2, varscan2
- UNK | c.120C>A p.F40L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99504523; called by muse, mutect2, varscan2
- VAV1 | c.182A>T p.N61I | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100408640; called by muse, mutect2, varscan2
- VCAN | c.2317A>T p.T773S | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.03); catalogued as COSV99424831; called by muse, mutect2, varscan2
- VPS37D | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.676); catalogued as COSV100265246; called by muse, mutect2, varscan2
- ZKSCAN7 | c.2067dup p.P690Tfs*3 | Frame Shift Ins (INS) | VAF 18/56 reads (32%) | catalogued as rs1222208598; called by mutect2, pindel, varscan2
- ZNF391 | c.813C>G p.H271Q | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99772424; called by muse, mutect2, varscan2
- ZNF665 | c.589T>A p.Y197N (on ENST00000600412; = p.Y262N on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101127953; called by muse, mutect2, varscan2
- CHRM2 | c.1000del p.S334Vfs*13 | Frame Shift Del (DEL) | VAF 36/82 reads (44%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.965A>T p.Q322L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF605 | c.815A>C p.Q272P | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); called by muse, mutect2
- ABCA3 | c.2928C>A p.S976= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV100068071; called by muse, mutect2, varscan2
- ADAM11 | c.1857C>T p.I619= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs779076826, COSV99567136; called by muse, mutect2, varscan2
- ANAPC5 | c.654A>G p.Q218= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs61757697, COSV99945957; called by muse, mutect2, varscan2
- ATMIN | c.636T>C p.T212= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV100214525; called by muse, mutect2, varscan2
- ATPAF1 | c.594A>G p.L198= (on ENST00000574428; = p.L221= on NM_022745.4) | Silent (SNP) | VAF 25/39 reads (64%) | catalogued as rs949379535, COSV100236004; called by muse, mutect2, varscan2
- BRINP1 | c.1908C>T p.G636= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as COSV99774518; called by muse, mutect2, varscan2
- CD300LB | c.405C>T p.T135= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100075317, COSV100075526; called by muse, mutect2, varscan2
- CDC42BPA | c.4044C>A p.T1348= (on ENST00000334218 / NM_001366019.2; = p.T1335= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV100503905; called by muse, mutect2, varscan2
- CFTR | c.4281C>T p.I1427= | Silent (SNP) | VAF 45/98 reads (46%) | catalogued as COSV99134244; called by muse, mutect2, varscan2
- CHML | c.21A>C p.T7= | Silent (SNP) | VAF 49/187 reads (26%) | catalogued as rs369552093; called by muse, mutect2, varscan2
- CLMP | c.549T>A p.S183= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV101507379; called by muse, mutect2, varscan2
- CNBD1 | c.642T>C p.Y214= | Silent (SNP) | VAF 51/148 reads (34%) | catalogued as COSV101575273; called by muse, mutect2, varscan2
- CSMD3 | c.4614T>A p.T1538= (on ENST00000297405 / NM_001363185.1; = p.T1434= on NM_052900.3) | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as COSV99825960; called by muse, mutect2, varscan2
- DDX1 | c.144A>T p.T48= | Silent (SNP) | VAF 221/492 reads (45%) | catalogued as rs766867235, COSV99245939; called by muse, mutect2, varscan2
- DOP1B | c.4333C>T p.L1445= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV101215083; called by muse, mutect2, varscan2
- DZIP1L | c.1716A>C p.P572= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV100551141; called by muse, mutect2, varscan2
- EFHC2 | c.654C>A p.T218= | Silent (SNP) | VAF 31/80 reads (39%) | catalogued as COSV101375442; called by muse, mutect2, varscan2
- FAM163A | c.264T>C p.C88= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100522914, COSV59202404; called by muse, mutect2, varscan2
- FRMD4B | c.3042C>T p.N1014= | Silent (SNP) | VAF 49/134 reads (37%) | catalogued as COSV101273340; called by muse, mutect2, varscan2
- FUT5 | c.1041A>T p.A347= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV99398549; called by muse, mutect2, varscan2
- H1-8 | c.159C>A p.P53= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs746578553, COSV60973962; called by muse, mutect2, varscan2
- HCN4 | c.3216C>T p.P1072= | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as COSV99983338; called by muse, mutect2, varscan2
- HPSE2 | c.66A>T p.L22= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as COSV65183423, COSV65187422; called by muse, mutect2, varscan2
- ITIH6 | c.3048C>T p.S1016= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as COSV99512886; called by muse, mutect2, varscan2
- KCNH3 | c.1518C>T p.R506= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs759915917, COSV99234784; called by muse, mutect2
- KIAA1109 | c.12966G>A p.Q4322= | Silent (SNP) | VAF 38/98 reads (39%) | catalogued as COSV99145977; called by muse, mutect2, varscan2
- KIF20B | c.4782T>C p.N1594= (on ENST00000371728 / NM_001284259.2; = p.N1554= on NM_016195.4) | Silent (SNP) | VAF 52/103 reads (50%) | catalogued as COSV99589546; called by muse, mutect2, varscan2
- LYL1 | c.153C>T p.S51= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99317014; called by muse, mutect2
- MACF1 | c.21426A>C p.G7142= (on ENST00000372915; = p.G5187= on NM_012090.5) | Silent (SNP) | VAF 60/123 reads (49%) | catalogued as COSV99241529; called by muse, mutect2, varscan2
- MAGEA8 | c.234T>A p.T78= | Silent (SNP) | VAF 27/62 reads (44%) | catalogued as COSV99674416; called by muse, mutect2, varscan2
- NHS | c.3252T>C p.R1084= | Silent (SNP) | VAF 73/140 reads (52%) | catalogued as COSV101196422; called by muse, mutect2, varscan2
- NOX3 | c.315C>T p.V105= | Silent (SNP) | VAF 52/57 reads (91%) | catalogued as rs747106586, COSV99342752; called by muse, mutect2, varscan2
- OBSCN | c.17829C>A p.V5943= | Silent (SNP) | VAF 16/66 reads (24%) | catalogued as COSV52741709; called by muse, mutect2, varscan2
- OSBPL7 | c.1713A>G p.R571= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99136551; called by muse, varscan2
- OTOP1 | c.90T>A p.P30= | Silent (SNP) | VAF 11/15 reads (73%) | catalogued as COSV99587392; called by muse, mutect2, varscan2
- OXCT1 | c.1509G>C p.G503= | Silent (SNP) | VAF 48/119 reads (40%) | catalogued as COSV52168962; called by muse, mutect2, varscan2
- P2RX6 | c.42A>T p.P14= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99488555; called by muse, mutect2, varscan2
- PAK4 | c.705G>T p.G235= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV100426384; called by muse, mutect2, varscan2
- PI3 | c.219T>G p.P73= | Silent (SNP) | VAF 44/81 reads (54%) | catalogued as COSV99714115; called by muse, mutect2, varscan2
- PLEKHG4 | c.2496T>C p.D832= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV100430683; called by muse, mutect2, varscan2
- POU3F4 | c.777G>T p.A259= | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as COSV100937170, COSV64538882; called by muse, mutect2, varscan2
- RIMS1 | c.4536T>A p.A1512= | Silent (SNP) | VAF 61/68 reads (90%) | catalogued as COSV99324435; called by muse, mutect2, varscan2
- SHANK1 | c.5547A>G p.P1849= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs752256461, COSV99520295; called by muse, mutect2, varscan2
- SPAG17 | c.2148T>C p.D716= | Silent (SNP) | VAF 63/142 reads (44%) | catalogued as rs772450473, COSV100308091, COSV60468846; called by muse, mutect2, varscan2
- STAB1 | c.7638C>T p.T2546= | Silent (SNP) | VAF 45/80 reads (56%) | catalogued as COSV100194581; called by muse, mutect2, varscan2
- SUGP2 | c.201A>T p.G67= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100431512; called by muse, mutect2, varscan2
- SYT9 | c.1158A>G p.G386= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100607601; called by muse, mutect2, varscan2
- TGM6 | c.1002C>G p.V334= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV99171685; called by muse, mutect2, varscan2
- TGM7 | c.1056A>T p.P352= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV101476822; called by muse, mutect2, varscan2
- TRPM6 | c.1044C>A p.I348= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as rs1477937710, COSV100665492; called by muse, mutect2, varscan2
- UGT2B4 | c.1479G>C p.V493= | Silent (SNP) | VAF 53/102 reads (52%) | catalogued as COSV100522216; called by muse, mutect2, varscan2
- VPS72 | c.474A>T p.R158= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV100614355; called by muse, mutect2, varscan2
- VTA1 | c.15A>G p.A5= | Silent (SNP) | VAF 17/21 reads (81%) | catalogued as rs1464484753, COSV62659062; called by muse, mutect2, varscan2
- ZC2HC1A | c.186A>G p.P62= | Silent (SNP) | VAF 58/139 reads (42%) | catalogued as COSV99803794; called by muse, mutect2, varscan2
- ZCRB1 | c.180T>C p.D60= | Silent (SNP) | VAF 59/93 reads (63%) | catalogued as COSV99861164; called by muse, mutect2, varscan2
- CD34 | c.598-129G>T | Intron (SNP) | VAF 32/106 reads (30%) | catalogued as rs1329335850, COSV100178172; called by mutect2, varscan2
- CTBP2 | c.58+12175A>T | Intron (SNP) | VAF 25/28 reads (89%) | catalogued as COSV100456168; called by muse, mutect2, varscan2
- RUFY3 | chr4:70793790 G>A | 3'Flank (SNP) | VAF 39/182 reads (21%) | catalogued as rs372273317; called by muse, mutect2, varscan2
